Somatic mutation profile of tumor specimen TCGA-HJ-7597-01A (aliquot TCGA-HJ-7597-01A-21D-2201-08) from TCGA case TCGA-HJ-7597, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,264 days).
Specimen TCGA-HJ-7597-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eaa4f97-c29b-46b9-8567-3ce639a3f3c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HJ-7597-10A (Blood Derived Normal), aliquot TCGA-HJ-7597-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53651989-0ae8-462a-8024-6ff6f678d1f0

The open-access MAF lists 889 somatic variants for this specimen: 652 protein-altering or splice-affecting, 224 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 440, Silent 224, Frame Shift Del 129, Nonsense Mutation 26, Frame Shift Ins 25, Splice Site 21, In Frame Del 9, Intron 7, Splice Region 2, RNA 2, 3'Flank 2, 5'UTR 1.

Variants (750 of 889; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7277G>A p.R2426Q (on ENST00000272895 / NM_173076.3; = p.R2108Q on NM_015657.3) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs761068277, COSV55975031; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.12560G>A p.R4187H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1556911750, CM1515152, COSV53363620; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 56/134 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A2M | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as rs1023050835, COSV59392388; called by muse, mutect2, varscan2
- ABCA5 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs780182861, COSV67019030; called by muse, mutect2, varscan2
- ABCC5 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.389); catalogued as rs761217800, COSV55593980; called by muse, mutect2, varscan2
- ABCD4 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1049484995, COSV53994370; called by muse, mutect2, varscan2
- ABL2 | c.2303C>T p.P768L (on ENST00000502732 / NM_007314.4; = p.P753L on NM_005158.5) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV61020492; called by muse, mutect2, varscan2
- ABRA | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 27/351 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.827); catalogued as COSV61733590; called by muse, mutect2
- AC011462.1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54199774; called by muse, mutect2, varscan2
- ACADM | c.388-2A>G p.X130_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as COSV63721073; called by muse, mutect2
- ACIN1 | c.1340dup p.V448Cfs*9 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs748065675; called by mutect2, varscan2
- ACTN4 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs760523958, COSV53150688; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.857G>T p.R286I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV52229745; called by muse, mutect2, varscan2
- ADAMTS4 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs114600134, COSV63489609, COSV63491343; called by muse, mutect2, varscan2
- ADAMTS7 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs773289537, COSV66308441; called by mutect2, varscan2
- ADAR | c.1643del p.P548Qfs*16 | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | catalogued as rs1189803379; called by mutect2, pindel, varscan2
- ADCY7 | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.6); catalogued as rs753781967, COSV54264668; called by muse, mutect2, varscan2
- ADRA1A | c.319del p.V107Cfs*22 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as COSV52357712; called by mutect2, pindel, varscan2
- AEBP1 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV56256613; called by muse, mutect2, varscan2
- AGBL5 | c.1266dup p.K423Qfs*28 | Frame Shift Ins (INS) | VAF 56/185 reads (30%) | catalogued as rs747733044; called by mutect2, varscan2
- AGO2 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55053245, COSV99073998; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel
- ALG13 | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.259); catalogued as COSV52644953; called by muse, mutect2, varscan2
- ALPK2 | c.6118T>C p.Y2040H | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64497009; called by muse, mutect2
- ANKRD13A | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752836978, COSV55678319; called by muse, mutect2, varscan2
- ANKRD34A | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60162039; called by muse, mutect2, varscan2
- ANXA11 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV55418530; called by muse, mutect2, varscan2
- AOC1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs577618065, COSV62869491; called by muse, mutect2, varscan2
- AOC2 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV53200323; called by muse, mutect2, varscan2
- AP2A2 | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100173045; called by muse, mutect2
- AP3B2 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55614186; called by muse, mutect2, varscan2
- AQP8 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54847567; called by muse, mutect2, varscan2
- AQR | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200095121; called by muse, mutect2, varscan2
- ARHGAP24 | c.1758del p.N587Tfs*61 (on ENST00000395184 / NM_001025616.3; = p.N494Tfs*61 on NM_031305.3) | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs1196259804, COSV51993294; called by mutect2, pindel, varscan2
- ARHGAP27 | c.1769A>G p.Y590C (on ENST00000428638 / NM_001282290.1; = p.Y249C on NM_199282.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65358740; called by muse, mutect2, varscan2
- ARHGAP33 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50162218; called by muse, mutect2, varscan2
- ARHGAP4 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs782676556, COSV61686161, COSV61686963; called by muse, mutect2, varscan2
- ARHGEF10L | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs747933795, COSV51440409; called by muse, mutect2
- ARHGEF18 | c.2186C>T p.A729V (on ENST00000359920 / NM_001130955.2; = p.A625V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs554029574, COSV60473891; called by muse, mutect2, varscan2
- ARID1A | c.2666dup p.M890Hfs*46 | Frame Shift Ins (INS) | VAF 10/43 reads (23%) | catalogued as rs1286891446; called by mutect2, pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 38/179 reads (21%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARIH2 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs746926650, COSV62706311; called by muse, mutect2, varscan2
- ARL16 | c.455T>C p.M152T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV61270284; called by muse, mutect2, varscan2
- ARMCX5 | c.1175A>T p.Y392F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV55767611; called by muse, mutect2, varscan2
- ARNT2 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57590471; called by muse, mutect2, varscan2
- ARNTL2 | c.919+2T>C p.X307_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV53828899; called by muse, mutect2, varscan2
- ATF4 | c.406dup p.Q136Pfs*44 | Frame Shift Ins (INS) | VAF 44/232 reads (19%) | catalogued as rs770192882; called by mutect2, varscan2
- ATP10A | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV63524011; called by muse, mutect2, varscan2
- ATP13A1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV52284436; called by muse, mutect2, varscan2
- AVPR2 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001619, CM940149, COSV61686962; called by muse, mutect2, varscan2
- BAHD1 | c.300del p.S101Afs*107 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as COSV69084900; called by mutect2, pindel, varscan2
- BAZ1B | c.108-1G>T p.X36_splice | Splice Site (SNP) | VAF 21/72 reads (29%) | catalogued as COSV59994569; called by muse, mutect2, varscan2
- BCL6 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176821201, COSV51655686; called by muse, mutect2, varscan2
- BCOR | c.19del p.L7Cfs*9 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | catalogued as COSV60718182; called by mutect2, pindel, varscan2
- BEST2 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50377684; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BEST3 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56996114; called by muse, mutect2, varscan2
- BICD1 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.414); catalogued as rs760462735, COSV55688073, COSV55688385; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.019); catalogued as rs145982160; called by muse, mutect2, varscan2
- BMPER | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749900138, COSV51814510; called by muse, mutect2, varscan2
- BRD1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367857228; called by muse, mutect2, varscan2
- BRD4 | c.2825C>T p.T942M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs765227557, COSV54594861; called by muse, mutect2, varscan2
- BTBD10 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs368074216, COSV53398498; called by muse, mutect2, varscan2
- BTBD7 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374714816; called by muse, mutect2, varscan2
- C10orf88 | c.348_351del p.C117Lfs*18 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as rs767900042; called by mutect2, pindel, varscan2
- C18orf54 | c.501T>A p.N167K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV55619438; called by muse, mutect2
- CABIN1 | c.4805T>C p.M1602T | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV54088930; called by muse, mutect2, varscan2
- CACNA1H | c.4624G>A p.V1542I | Missense Mutation (SNP) | VAF 74/319 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs745495784, COSV61986245, COSV62003360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG5 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs141669982; called by muse, mutect2, varscan2
- CACUL1 | c.700T>C p.F234L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60996655; called by muse, mutect2
- CACYBP | c.423T>A p.S141R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62881650; called by muse, mutect2, varscan2
- CAMSAP1 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as rs772514233, COSV56728372; called by muse, mutect2, varscan2
- CARMIL2 | c.2042A>G p.Q681R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV58031927; called by muse, mutect2, varscan2
- CCDC116 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 85/298 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); catalogued as COSV53038756; called by muse, mutect2, varscan2
- CCDC124 | c.604_606del p.K202del | In Frame Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs756106175; called by pindel, varscan2
- CCDC180 | c.3896C>T p.A1299V | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV63835217; called by muse, mutect2, varscan2
- CCDC3 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs957107751, COSV66560501; called by muse, mutect2, varscan2
- CCDC80 | c.478T>G p.S160A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV52819862; called by muse, mutect2, varscan2
- CCDC91 | c.882A>C p.E294D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60348306; called by muse, mutect2, varscan2
- CCM2L | c.141del p.D48Tfs*27 | Frame Shift Del (DEL) | VAF 39/151 reads (26%) | catalogued as COSV52949350; called by mutect2, pindel, varscan2
- CD4 | c.498dup p.K167Efs*13 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | catalogued as rs781937995; called by mutect2, varscan2
- CD83 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs147342996, COSV64788109; called by muse, mutect2, varscan2
- CDC42BPB | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs368109666; called by muse, mutect2, varscan2
- CDH16 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs868685936, COSV55339597; called by muse, mutect2, varscan2
- CEACAM1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs768241278, COSV50732690; called by muse, mutect2, varscan2
- CEACAM8 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as COSV54991774; called by muse, mutect2
- CEL | c.704T>C p.L235P (on ENST00000673714; = p.L232P on NM_001807.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV60829575; called by muse, mutect2, varscan2
- CELSR1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53099566; called by muse, mutect2, varscan2
- CELSR3 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV51149059; called by muse, mutect2, varscan2
- CEP85L | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63828682; called by muse, mutect2, varscan2
- CEP95 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782568738, COSV73609620; called by muse, mutect2
- CGGBP1 | c.40C>G p.R14G | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV58853047; called by muse, mutect2, varscan2
- CHD8 | c.1004C>T p.A335V (on ENST00000646647 / NM_001170629.2; = p.A56V on NM_020920.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV67872665; called by muse, mutect2
- CHRM2 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV57784348, COSV57786228; called by muse, mutect2, varscan2
- CHRM3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs201425358; called by muse, mutect2, varscan2
- CHRNA6 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV52381000; called by muse, mutect2, varscan2
- CIC | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV50663481; called by mutect2, varscan2
- CIZ1 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs754102259, COSV52972100, COSV52974458; called by muse, mutect2, varscan2
- CLCN4 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66466765; called by muse, mutect2, varscan2
- CLDN5 | c.419C>T p.A140V (on ENST00000618236 / NM_001363066.2; = p.A225V on NM_003277.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV54247488; called by muse, mutect2, varscan2
- CLIP2 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs1352937677, COSV56286082; called by muse, mutect2, varscan2
- CLIP3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1274410010, COSV62111891; called by muse, mutect2, varscan2
- CMYA5 | c.11232G>T p.E3744D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71409419; called by muse, mutect2, varscan2
- CNN2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs370563052; called by muse, mutect2, varscan2
- CNOT6 | c.665del p.K222Rfs*8 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1216950236, COSV99993855; called by mutect2, pindel, varscan2
- CNPY3 | c.482A>C p.D161A | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV65710049; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN2 | c.1436G>A p.S479N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59348270; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | catalogued as rs374805044; called by mutect2, varscan2
- COG8 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1407137102, COSV54743559; called by muse, mutect2, varscan2
- COL27A1 | c.4819G>A p.G1607S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs768729888, COSV61924416; called by muse, mutect2, varscan2
- COL27A1 | c.4873-2A>G p.X1625_splice | Splice Site (SNP) | VAF 10/122 reads (8%) | catalogued as COSV61930698; called by muse, mutect2
- COL6A2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as rs755822013, COSV56015773; called by muse, mutect2, varscan2
- CPSF1 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV62942420; called by muse, varscan2
- CPT1B | c.925A>C p.M309L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV56418999; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CREBBP | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1425065110, COSV52132932, COSV52140415, COSV52141766; called by muse, mutect2, varscan2
- CRIM1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs767692280, COSV54872498; called by muse, mutect2, varscan2
- CSE1L | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.463); catalogued as rs746870335, COSV53705094; called by muse, mutect2, varscan2
- CSF1 | c.1153del p.Q385Rfs*92 | Frame Shift Del (DEL) | VAF 9/102 reads (9%) | catalogued as rs1557737366; called by mutect2, pindel
- CSK | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | catalogued as COSV54975950; called by muse, mutect2, varscan2
- CSMD2 | c.9232C>T p.R3078C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1283736318, COSV53915658, COSV53961019; called by muse, mutect2
- CSMD3 | c.4733A>C p.Q1578P (on ENST00000297405 / NM_001363185.1; = p.Q1474P on NM_052900.3) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52315250; called by muse, mutect2, varscan2
- CTDSP2 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66080279; called by muse, mutect2, varscan2
- CTNNA3 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs773609785, COSV65583084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.2215A>G p.T739A | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52915392; called by muse, varscan2
- CUX1 | c.2389del p.Q797Rfs*11 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV99472907; called by pindel, varscan2
- CYP11A1 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as rs750547647, COSV51432206, COSV51434813; called by muse, mutect2, varscan2
- CYP2B6 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs755570515, COSV57845408; called by muse, mutect2, varscan2
- DACH2 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV100913391; called by mutect2, varscan2
- DCAF5 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs548708375, COSV58463082; called by muse, mutect2, varscan2
- DCHS1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV55034262, COSV55039579; called by muse, mutect2, varscan2
- DDR1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61325692; called by muse, varscan2
- DEFB125 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as rs375564330; called by muse, mutect2, varscan2
- DEK | c.897del p.E300Kfs*13 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as COSV99788881; called by mutect2, pindel, varscan2
- DFFA | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV65478245; called by muse, mutect2
- DGKK | c.2245A>G p.I749V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65709379; called by muse, mutect2, varscan2
- DHRS1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs752733121, COSV55385378; called by muse, mutect2, varscan2
- DISP3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201224302, COSV53837232; called by muse, mutect2, varscan2
- DLEC1 | c.4550A>G p.Y1517C | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs1335725581, COSV57180526; called by muse, mutect2, varscan2
- DLEC1 | c.4954C>T p.Q1652* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as rs772223976, COSV57180537; called by muse, mutect2, varscan2
- DMWD | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs765625836, COSV52182251; called by muse, mutect2, varscan2
- DNAH10 | c.12239C>T p.P4080L (on ENST00000409039; = p.P4019L on NM_207437.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs754875926, COSV69001322; called by muse, mutect2, varscan2
- DNAH10 | c.12424A>G p.K4142E (on ENST00000409039; = p.K4081E on NM_207437.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV69001327; called by muse, mutect2, varscan2
- DNAH5 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775816222, COSV54250857; called by mutect2, varscan2
- DNAH7 | c.2957C>T p.T986M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs202143138; called by muse, mutect2, varscan2
- DNAJB4 | c.64A>T p.K22* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV66132121; called by muse, mutect2, varscan2
- DNMBP | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV60633000; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs748134881; called by mutect2, varscan2
- DRAM1 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs748500198, COSV51599703; called by muse, mutect2, varscan2
- DRD5 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58580380; called by muse, mutect2
- DYNC2H1 | c.12917dup p.N4306Kfs*18 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs761970784; called by mutect2, pindel, varscan2
- DZIP1L | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV59523411; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs371866621, COSV62567482; called by muse, mutect2, varscan2
- EEFSEC | c.966A>G p.I322M | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54619413; called by muse, mutect2, varscan2
- EGFLAM | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 31/130 reads (24%) | catalogued as COSV59293347, COSV59317015; called by muse, mutect2, varscan2
- EHBP1L1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs757355051, COSV58574970; called by muse, mutect2, varscan2
- EIF2AK2 | c.788T>C p.F263S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51799259; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF4E | c.221+1G>A p.X74_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV55189296; called by muse, mutect2, varscan2
- ELOVL3 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64175013; called by muse, mutect2, varscan2
- EP400 | c.4900C>T p.R1634* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100201380; called by muse, mutect2, varscan2
- EP400 | c.5402C>T p.P1801L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs545633950, COSV57786154; called by muse, mutect2, varscan2
- EPN2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139687943; called by muse, mutect2, varscan2
- EPYC | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs758493947, COSV53802093; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV4 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765893929, COSV52256571; called by muse, mutect2, varscan2
- ETV6 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs149660037, COSV67154270; called by muse, mutect2, varscan2
- EVI2A | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55986955; called by muse, mutect2, varscan2
- EVL | c.560dup p.P188Tfs*108 (on ENST00000402714 / NM_001330221.2; = p.P190Tfs*108 on NM_016337.3) | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs746606863; called by mutect2, varscan2
- EXD2 | c.1634C>T p.A545V (on ENST00000312994 / NM_001193362.1; = p.A420V on NM_018199.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.55); catalogued as COSV57282166; called by muse, mutect2, varscan2
- EXOC2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as rs145867129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA1 | c.1699-1G>A p.X567_splice | Splice Site (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100379569; called by muse, mutect2, varscan2
- EYA4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1283835268, COSV62060591; called by muse, mutect2
- F9 | c.878del p.K293Sfs*4 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | catalogued as CM151338; called by mutect2, pindel, varscan2
- FAM104A | c.9del p.R4Afs*64 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as rs770000277; called by mutect2, pindel, varscan2
- FAM117A | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53604236; called by muse, mutect2, varscan2
- FAM217A | c.235-2A>C p.X79_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV51162184; called by muse, mutect2, varscan2
- FAM53C | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53512935; called by muse, mutect2
- FAM83C | c.715T>C p.Y239H | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373419404; called by muse, mutect2, varscan2
- FBXL3 | c.1079del p.N360Ifs*7 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV62919267; called by mutect2, pindel, varscan2
- FBXO15 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1363832799, COSV54043164; called by muse, mutect2, varscan2
- FBXO27 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs377599554; called by muse, mutect2, varscan2
- FHOD1 | c.753C>T p.T251= | Splice Region (SNP) | VAF 5/77 reads (6%) | catalogued as rs1331852035, COSV50769433; called by muse, mutect2
- FIGN | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.937); catalogued as rs375256647; called by muse, mutect2, varscan2
- FNBP1L | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1420620030, COSV53092550; called by muse, mutect2, varscan2
- FPR1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.427); catalogued as rs933017940, COSV59050877; called by muse, mutect2, varscan2
- FRMD4B | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs376555402; called by muse, mutect2, varscan2
- FRMPD2 | c.1117T>A p.S373T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV59723623; called by muse, mutect2, varscan2
- FRMPD3 | c.4238del p.G1413Afs*12 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV52189566; called by mutect2, pindel, varscan2
- FSTL4 | c.1608G>T p.Q536H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54785726; called by muse, mutect2, varscan2
- G2E3 | c.975_978del p.R325Sfs*11 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1322753123; called by mutect2, pindel, varscan2
- GAA | c.2116C>A p.L706I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100163301; called by muse, mutect2, varscan2
- GABRD | c.189dup p.V64Rfs*365 | Frame Shift Ins (INS) | VAF 37/136 reads (27%) | catalogued as rs765094085; called by mutect2, varscan2
- GAN | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs749359745, COSV73721390; called by muse, mutect2, varscan2
- GCDH | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs775606471, CM156417, COSV53367003; called by muse, mutect2, varscan2
- GEMIN5 | c.3611T>A p.I1204N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53563618; called by muse, mutect2, varscan2
- GFPT2 | c.1547-2A>G p.X516_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | catalogued as COSV53812414; called by muse, mutect2, varscan2
- GLE1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV59410536; called by muse, mutect2
- GNA15 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs201355990, COSV53588170; called by muse, mutect2, varscan2
- GPAT3 | c.707del p.L236* | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as COSV100023217; called by mutect2, pindel, varscan2
- GPATCH8 | c.3464G>A p.R1155Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs376437315; called by muse, mutect2, varscan2
- GPR162 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.703); catalogued as rs1555119660, COSV50595779; called by muse, mutect2, varscan2
- GPR179 | c.1996G>A p.A666T (on ENST00000621958; = p.A665T on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.047); catalogued as rs779762920; called by muse, mutect2, varscan2
- GPR35 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs760148943, COSV60578594; called by muse, mutect2, varscan2
- GPSM3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1191563706, COSV66683701; called by muse, mutect2, varscan2
- GREB1 | c.5375C>T p.P1792L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs780878773, COSV52196125; called by muse, mutect2, varscan2
- GRIA1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs146865938; called by muse, varscan2
- GRIA3 | c.2428G>A p.G810S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs767624862, COSV99990566, COSV99990954; called by muse, mutect2, varscan2
- GRIN2A | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149698593, COSV58018962; called by muse, mutect2, varscan2
- GSG1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs772207656, COSV60970033, COSV60970738, COSV60973447; called by muse, mutect2, varscan2
- GTF3C1 | c.5963G>A p.R1988H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760347646, COSV62239601, COSV62245106; called by muse, mutect2, varscan2
- GTSF1L | c.363del p.P122Lfs*50 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs1568892529; called by mutect2, pindel, varscan2
- H2AC8 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV55127878; called by muse, mutect2, varscan2
- H2BC7 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV61912403; called by muse, mutect2, varscan2
- HAO1 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1175865614, COSV66493796; called by muse, mutect2, varscan2
- HAPLN3 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1185105280, COSV61369213; called by muse, mutect2, varscan2
- HCFC1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV60077586; called by muse, mutect2, varscan2
- HCN1 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 35/124 reads (28%) | catalogued as rs534013981, COSV57513022, COSV57529311; called by muse, mutect2, varscan2
- HCN2 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV52118752; called by muse, mutect2, varscan2
- HDAC4 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs754027484, COSV61876006; called by muse, mutect2, varscan2
- HDAC6 | c.1531A>G p.M511V | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as COSV61930597; called by muse, mutect2, varscan2
- HDAC9 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs368028612, COSV67778096; called by mutect2, varscan2
- HDC | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370055047; called by muse, mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HERC6 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs200315029, COSV52034372; called by muse, mutect2, varscan2
- HMCN1 | c.14451G>T p.W4817C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54897062; called by muse, mutect2, varscan2
- HOXB3 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57488220; called by muse, mutect2, varscan2
- HSD17B1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs61738807, COSV56798617; called by muse, mutect2, varscan2
- ICE2 | c.1576A>G p.N526D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1257750202, COSV55033993; called by muse, mutect2, varscan2
- ID3 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as COSV65801490; called by muse, mutect2, varscan2
- IDE | c.110del p.K37Rfs*6 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs1307048524; called by mutect2, pindel, varscan2
- IFT172 | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.548); catalogued as COSV53133467; called by muse, mutect2
- IGDCC4 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs768453154, COSV61539200; called by muse, mutect2, varscan2
- IGFL2 | c.166G>A p.A56T (on ENST00000377693 / NM_001135113.2; = p.A67T on NM_001002915.2) | Missense Mutation (SNP) | VAF 106/392 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs754195953, COSV66616668; called by muse, mutect2, varscan2
- IHH | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs778096124, COSV55394049; called by muse, mutect2, varscan2
- IL2RB | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.088); catalogued as rs754692430, COSV53428507; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- IL36A | c.415A>G p.I139V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV52083843; called by muse, mutect2, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs776023104; called by mutect2, pindel, varscan2
- INTU | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58874653; called by muse, mutect2, varscan2
- INVS | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as rs758506682, COSV52442058, COSV52449875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs759821884; called by mutect2, pindel*, varscan2
- IQGAP1 | c.3790C>T p.R1264W | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs763205486, COSV51591287; called by muse, mutect2, varscan2
- IRAK1 | c.1028+2T>C p.X343_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV57656855; called by muse, mutect2, varscan2
- IRX6 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV51860175, COSV51862251; called by muse, varscan2
- JAK1 | c.3169A>G p.K1057E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53810819; called by muse, mutect2, varscan2
- JAK1 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs1306467125, COSV61096397; called by muse, mutect2, varscan2
- JPH2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65903570; called by muse, mutect2, varscan2
- KBTBD6 | c.1282A>G p.M428V | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.076); catalogued as COSV65271981; called by muse, mutect2
- KCND1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as rs932616236, COSV54415915; called by muse, mutect2, varscan2
- KCNH1 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55094350, COSV99659737; called by muse, mutect2, varscan2
- KCNV2 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs371445689, COSV66057510; called by muse, mutect2
- KDELR2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51727900; called by muse, mutect2, varscan2
- KDF1 | c.429del p.S144Afs*104 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV57671558; called by mutect2, pindel, varscan2
- KDM6B | c.3551del p.P1184Lfs*31 | Frame Shift Del (DEL) | VAF 84/264 reads (32%) | catalogued as COSV99642676; called by mutect2, pindel, varscan2
- KIAA1109 | c.5638C>T p.R1880* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs756528593, COSV52691712; called by muse, mutect2, varscan2
- KIAA1586 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1357119738, COSV66057432; called by muse, mutect2, varscan2
- KIAA1958 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs538902700, COSV100515775, COSV61723537; called by muse, mutect2, varscan2
- KIF27 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs367944774; called by muse, mutect2, varscan2
- KIF2B | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs762901378, COSV52128005; called by muse, mutect2, varscan2
- KIRREL1 | c.1853G>T p.R618M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as COSV63291287; called by muse, mutect2, varscan2
- KLHDC7A | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs566257503, COSV68768959; called by muse, mutect2, varscan2
- KLHL18 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs149811108; called by muse, mutect2, varscan2
- KLHL26 | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56319603; called by muse, mutect2
- KRT14 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs747163920, COSV51420609; called by muse, mutect2, varscan2
- KRT23 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201868895, COSV52928999; called by muse, mutect2, varscan2
- KRT8 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs768679214, COSV53179155; called by muse, mutect2, varscan2
- KRTAP12-2 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370804825; called by muse, mutect2, varscan2
- LAMA4 | c.3568G>T p.A1190S (on ENST00000230538 / NM_001105206.3; = p.A1183S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV57904665; called by muse, mutect2, varscan2
- LDLRAP1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV65474157; called by muse, mutect2, varscan2
- LIG4 | c.1420G>T p.G474* | Nonsense Mutation (SNP) | VAF 47/187 reads (25%) | catalogued as COSV63598071; called by muse, mutect2, varscan2
- LILRA4 | c.1424del p.P475Qfs*69 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs758325116, COSV52491499; called by mutect2, pindel, varscan2
- LIN9 | c.1367A>G p.Q456R (on ENST00000366808 / NM_001270410.2; = p.Q401R on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV60247036; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375447132; called by muse, mutect2, varscan2
- LMO7 | c.2842G>A p.A948T (on ENST00000357063; = p.A629T on NM_005358.5) | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs370412695; called by muse, mutect2, varscan2
- LONRF3 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.479); catalogued as COSV59156903; called by muse, mutect2, varscan2
- LOXL4 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as rs555163440, COSV53259272; called by muse, mutect2, varscan2
- LRBA | c.5996C>G p.P1999R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63964653; called by muse, mutect2, varscan2
- LRBA | c.2005-1G>T p.X669_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100841718; called by muse, mutect2, varscan2
- LRP1 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.953); catalogued as rs755987592, COSV54525611; called by muse, mutect2, varscan2
- LRP11 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs749525159, COSV53335428; called by muse, mutect2, varscan2
- LRSAM1 | c.1374G>T p.E458D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100031590; called by muse, mutect2
- LYPD4 | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 38/162 reads (23%) | catalogued as rs782812231, COSV58027470; called by muse, mutect2, varscan2
- LYSMD1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs369851641; called by muse, mutect2, varscan2
- LZTS2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV64652932; called by muse, mutect2, varscan2
- MACF1 | c.17317G>A p.A5773T (on ENST00000372915; = p.A3815T on NM_012090.5) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV57133186; called by muse, mutect2, varscan2
- MADD | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs770084863, COSV60628323; called by muse, mutect2, varscan2
- MAGEA4 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52343091; called by muse, mutect2
- MAGI1 | c.2996G>T p.G999V (on ENST00000402939 / NM_001033057.2; = p.G1028V on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100441461, COSV58325059; called by muse, mutect2
- MAGI2 | c.104del p.G35Afs*13 | Frame Shift Del (DEL) | VAF 34/176 reads (19%) | catalogued as COSV62634980; called by mutect2, pindel, varscan2
- MAT2B | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV55202280; called by muse, mutect2, varscan2
- MAZ | c.39dup p.F14Lfs*34 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | catalogued as rs767720617; called by mutect2, varscan2
- MAZ | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as rs768483206, COSV50718473; called by muse, mutect2, varscan2
- MBD1 | c.1036C>T p.R346W (on ENST00000269468 / NM_001323950.1; = p.R323W on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568217739, COSV53997596; called by muse, mutect2, varscan2
- MED12L | c.5318G>A p.R1773H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs149611856, COSV56372938; called by muse, mutect2, varscan2
- MEP1A | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.129); catalogued as COSV57921791; called by muse, mutect2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs745891632; called by mutect2, varscan2
- MIA3 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs761864266, COSV60511553; called by muse, mutect2, varscan2
- MIB2 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.318); catalogued as COSV61757486; called by muse, mutect2, varscan2
- MICALL2 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147056642, COSV52518798; called by muse, mutect2
- MIDEAS | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54098924; called by muse, mutect2, varscan2
- MIGA1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769147848, COSV66223478; called by muse, mutect2, varscan2
- MINAR1 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as rs761261007, COSV59586433; called by muse, mutect2, varscan2
- MKI67 | c.9283C>T p.R3095C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs754001305, COSV64076880; called by mutect2, varscan2
- MLLT10 | c.1771G>A p.V591I (on ENST00000307729 / NM_001195626.3; = p.V607I on NM_004641.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV57004193; called by muse, mutect2, varscan2
- MLXIP | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs748755787, COSV59837884; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs750319971; called by mutect2, varscan2
- MRAP | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs755085204, COSV57936565; called by muse, mutect2, varscan2
- MROH1 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs961461899; called by muse, mutect2
- MRPL49 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as rs539335985, COSV53695611; called by muse, mutect2, varscan2
- MTCL1 | c.3691C>T p.R1231C (on ENST00000306329 / NM_001378206.1; = p.R912C on NM_015210.4) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1483816850, COSV60411640; called by muse, mutect2, varscan2
- MTOR | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1031980569, COSV63870844; called by muse, mutect2, varscan2
- MXRA5 | c.6256G>A p.G2086S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201160511, COSV54250085; called by muse, mutect2, varscan2
- MYBBP1A | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs533085700, COSV54604237; called by muse, mutect2, varscan2
- MYDGF | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53561676; called by muse, mutect2, varscan2
- MYH10 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs778816874, COSV52611041; called by muse, mutect2, varscan2
- MYH2 | c.4163G>A p.R1388H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs745754711, COSV55432911; ClinVar: uncertain significance; called by muse, varscan2
- MYH7B | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs375916720; called by muse, mutect2, varscan2
- MYO5C | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs374189950, COSV55907185; called by muse, mutect2, varscan2
- MYO9B | c.6178del p.R2060Gfs*68 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1388909247; called by mutect2, pindel, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.026); catalogued as rs376382958, COSV62335147; called by mutect2, varscan2
- NBAS | c.4350G>A p.G1450= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as COSV55733304; called by muse, mutect2, varscan2
- NCAPD3 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769967939, COSV73244926; called by muse, mutect2, varscan2
- NCBP1 | c.1061T>C p.V354A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64317490; called by muse, mutect2, varscan2
- NCEH1 | c.1087C>T p.R363C (on ENST00000538775; = p.R323C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs754711926, COSV56438285; called by muse, mutect2, varscan2
- NCOR1 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51960044, COSV51995687; called by muse, mutect2, varscan2
- NCOR2 | c.2050A>G p.K684E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV62304405; called by muse, mutect2, varscan2
- NCOR2 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370836867; called by muse, mutect2, varscan2
- NDUFB3 | c.142A>G p.N48D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99428313; called by muse, mutect2, varscan2
- NFAT5 | c.3176A>T p.N1059I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV63032588; called by muse, mutect2, varscan2
- NFKB1 | c.1858C>T p.H620Y (on ENST00000394820 / NM_001382627.1; = p.H621Y on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56960952; called by muse, mutect2, varscan2
- NGB | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV53611113; called by muse, mutect2, varscan2
- NHLRC1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV61481863; called by muse, mutect2, varscan2
- NIBAN3 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as rs778224526, COSV56309020, COSV56313798; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as COSV53499514; called by mutect2, varscan2
- NLRP1 | c.2855A>G p.K952R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV52578585; called by muse, mutect2, varscan2
- NLRP11 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561555803, COSV64086215; called by muse, mutect2, varscan2
- NOTCH1 | c.1873T>G p.Y625D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53093171; called by muse, mutect2, varscan2
- NOTCH4 | c.1388G>A p.C463Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66683704; called by muse, mutect2, varscan2
- NPAT | c.3587G>A p.R1196Q | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs779721763, COSV53721717; called by muse, mutect2, varscan2
- NR2F2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV67684114; called by muse, mutect2
- NRF1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs764173748, COSV56210750; called by muse, mutect2, varscan2
- NUCKS1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as rs764048321, COSV65652695; called by muse, mutect2, varscan2
- NUDT14 | c.428+2T>C p.X143_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100242041; called by muse, mutect2, varscan2
- NUDT3 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1336809587, COSV74119402, COSV74119456; called by muse, mutect2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1566064574; called by pindel, varscan2
- NUP88 | c.234_236del p.F78del | In Frame Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs1413680729; called by pindel, varscan2
- NUP93 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs146068835; called by muse, mutect2, varscan2
- OBP2B | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64402915; called by muse, mutect2, varscan2
- OBSCN | c.14761G>A p.V4921M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs563420104, COSV52756596; called by muse, mutect2, varscan2
- OLFML3 | c.795dup p.Y266Lfs*14 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs753594963; called by mutect2, varscan2
- OR1J4 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as rs769279903, COSV61589868, COSV61590303; called by muse, mutect2, varscan2
- OR51B2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 58/80 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs770237512, COSV60917092; called by muse, mutect2, varscan2
- OR5A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs796662079, COSV57378244; called by muse, mutect2, varscan2
- PAPLN | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs370335884; called by muse, mutect2, varscan2
- PAQR3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55011892, COSV99785414; called by muse, mutect2, varscan2
- PARP12 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV54937092; called by muse, mutect2, varscan2
- PARP4 | c.1301G>T p.R434M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101131693; called by mutect2, varscan2
- PAX1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV68273362, COSV68273844; called by muse, mutect2
- PCDH10 | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV52103718; called by muse, mutect2, varscan2
- PCDHA12 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV56543138; called by muse, mutect2, varscan2
- PCDHA4 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.274); catalogued as COSV63545904; called by muse, mutect2, varscan2
- PCDHGA8 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.737); catalogued as rs143444747; called by muse, mutect2, varscan2
- PCNX1 | c.3604del p.C1202Vfs*4 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as COSV99456874; called by mutect2, pindel, varscan2
- PCNX3 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1007283650, COSV63140741; called by muse, mutect2, varscan2
- PCSK5 | c.4783C>T p.R1595C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs773065504, COSV101377521; called by muse, mutect2, varscan2
- PDCD11 | c.4613C>T p.A1538V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754425637, COSV53297807; called by muse, mutect2, varscan2
- PDGFRB | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs544478083, COSV55808873; called by muse, mutect2, varscan2
- PENK | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as COSV59242866; called by muse, mutect2, varscan2
- PEX5L | c.858A>C p.E286D | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV55857132; called by muse, mutect2, varscan2
- PHF8 | c.1246C>T p.R416C (on ENST00000357988 / NM_001184896.1; = p.R380C on NM_015107.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57683957; called by muse, mutect2, varscan2
- PHLDB1 | c.3394T>C p.C1132R | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1029999685, COSV61881794; called by muse, mutect2, varscan2
- PI16 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV65448663; called by muse, mutect2, varscan2
- PIK3CG | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs762164881, COSV63246672; called by muse, mutect2, varscan2
- PJA1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.998); catalogued as COSV64053733; called by muse, mutect2, varscan2
- PLEC | c.1515G>T p.K505N (on ENST00000322810 / NM_201380.4; = p.K395N on NM_000445.5) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59694223; called by muse, mutect2, varscan2
- PLEKHF1 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.172); catalogued as COSV71410393; called by muse, mutect2
- PLS1 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV61835472; called by muse, mutect2, varscan2
- PLXNA2 | c.92dup p.A32Sfs*13 | Frame Shift Ins (INS) | VAF 20/95 reads (21%) | catalogued as rs756284848; called by mutect2, varscan2
- PLXNA3 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs143738443, COSV63755345; called by muse, mutect2
- PLXNA4 | c.5351C>T p.T1784M | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372160247; called by muse, mutect2, varscan2
- PLXNB3 | c.4015C>T p.R1339C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781808141, COSV62802098; called by muse, mutect2, varscan2
- PM20D1 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100900210; called by muse, mutect2
- POGZ | c.632_633insA p.V212Cfs*103 | Frame Shift Ins (INS) | VAF 40/294 reads (14%) | catalogued as COSV99652907; called by mutect2, pindel, varscan2
- POLD1 | c.2251-1G>T p.X751_splice | Splice Site (SNP) | VAF 41/162 reads (25%) | catalogued as COSV70957282; called by muse, mutect2, varscan2
- PON1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs756961976, COSV55933915; called by muse, mutect2, varscan2
- POU3F3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722441; called by muse, mutect2, varscan2
- PPIE | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV60972847; called by muse, mutect2, varscan2
- PPP1R12B | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61123674; called by muse, mutect2, varscan2
- PPP1R3A | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs533705714, COSV52882352; called by muse, mutect2, varscan2
- PRDM10 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760125470, COSV58802563; called by muse, mutect2, varscan2
- PRDM2 | c.2954C>T p.P985L | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs374204071, COSV52444111; called by muse, varscan2
- PREX1 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs765882639, COSV64250654; called by muse, mutect2, varscan2
- PRICKLE2 | c.1061T>C p.L354P (on ENST00000295902; = p.L298P on NM_198859.4) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55771662; called by muse, mutect2, varscan2
- PRKCG | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV54732754, COSV54733455; called by muse, mutect2, varscan2
- PRKCSH | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs886054197, COSV52954058; called by muse, mutect2
- PRKG2 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs753582287, COSV52331719; called by muse, mutect2, varscan2
- PRMT9 | c.493A>T p.I165F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100482000, COSV59361524; called by muse, mutect2, varscan2
- PRPF3 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553872873, COSV61396364; called by muse, mutect2, varscan2
- PRPF40A | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs1218032815, COSV68359369; called by muse, mutect2, varscan2
- PRR23B | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.506); catalogued as COSV61493105; called by muse, mutect2, varscan2
- PRR35 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs368109839; called by muse, mutect2, varscan2
- PRRG3 | c.134_136del p.E45del | In Frame Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs762947436; called by pindel, varscan2
- PRSS58 | c.413G>T p.W138L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73488659, COSV73488857; called by muse, mutect2, varscan2
- PSAP | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1159577504, COSV67551188; called by muse, mutect2, varscan2
- PSD | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749171096, COSV50060889; called by muse, mutect2, varscan2
- PTPN13 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as rs773296258, COSV57417233; called by muse, mutect2, varscan2
- PTPRD | c.2864C>A p.T955N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs763256154, COSV61977473, COSV61980890; called by muse, mutect2, varscan2
- PTPRE | c.2035T>C p.Y679H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54558692; called by muse, mutect2, varscan2
- PTPRF | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765844810, COSV63448789; called by muse, mutect2, varscan2
- PTPRF | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.206); catalogued as COSV63448793; called by muse, mutect2, varscan2
- PTPRS | c.4736C>T p.P1579L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs372226485; called by muse, mutect2, varscan2
- PTX4 | c.783G>T p.Q261H (on ENST00000447419 / NM_001328608.2; = p.Q256H on NM_001013658.1) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV53519658; called by muse, mutect2, varscan2
- PUS7 | c.1435T>C p.Y479H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62678448; called by muse, mutect2, varscan2
- PWWP2A | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV61048039; called by muse, mutect2, varscan2
- PXDN | c.3730C>T p.R1244* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV53246001; called by muse, mutect2
- QPCTL | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1459279211, COSV50004897; called by muse, mutect2, varscan2
- R3HCC1L | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV54400624, COSV54405250; called by muse, mutect2
- RAB40C | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV50195531; called by muse, mutect2, varscan2
- RABGGTA | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99397697; called by muse, mutect2
- RAD54L2 | c.3076G>A p.V1026M | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as rs749850835, COSV56581543; called by muse, mutect2, varscan2
- RAD54L2 | c.3494C>T p.A1165V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.039); catalogued as COSV56581551; called by muse, mutect2, varscan2
- RAI1 | c.5041A>G p.S1681G | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV55399017; called by muse, mutect2
- RALGDS | c.1791+1G>A p.X597_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV64429577; called by muse, mutect2, varscan2
- RASGRF2 | c.3552+2T>C p.X1184_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as COSV54131938; called by muse, mutect2, varscan2
- RCBTB2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs146429069; called by muse, mutect2, varscan2
- REEP5 | c.560_562del p.K187del | In Frame Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs772705017; called by pindel, varscan2
- RGS12 | c.4195C>T p.R1399W (on ENST00000336727; = p.R751W on NM_198227.2) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs777921323, COSV58750078; called by mutect2, varscan2
- RGS14 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs374571122; called by muse, mutect2
- RGS20 | c.691C>G p.P231A (on ENST00000297313 / NM_170587.4; = p.P84A on NM_003702.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52022272; called by muse, mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as COSV54616696; called by mutect2, pindel, varscan2
- RILPL1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as rs779371624, COSV61553674; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 45/191 reads (24%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs377765604, COSV68457897; called by muse, mutect2, varscan2
- ROR2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as COSV65220274; called by muse, mutect2, varscan2
- RPGR | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58833546; called by muse, mutect2, varscan2
- RPL10L | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53559786, COSV53561521; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs771894711, COSV64823277; called by muse, mutect2, varscan2
- RRBP1 | c.2218G>A p.G740R (on ENST00000377813 / NM_001365613.2; = p.G307R on NM_004587.3) | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.905); catalogued as rs547155729, COSV55703857, COSV99853931; called by muse, mutect2, varscan2
- RUBCN | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189739719, COSV56373973; called by muse, mutect2, varscan2
- RUSF1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs765686337, COSV57894536; called by muse, mutect2, varscan2
- S100PBP | c.524_525del p.S175Ffs*12 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs1477434041; called by pindel, varscan2
- SAMD9L | c.4547del p.N1516Mfs*10 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV59083791; called by mutect2, varscan2
- SCAF1 | c.2053del p.A685Pfs*53 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1377517037; called by mutect2, varscan2
- SCAF4 | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.201); catalogued as COSV54592038; called by muse, mutect2, varscan2
- SCFD2 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.475); catalogued as COSV66376901; called by muse, mutect2, varscan2
- SCML4 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs766078524, COSV64638068; called by muse, mutect2, varscan2
- SCRG1 | c.96A>G p.I32M | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV56636101; called by muse, mutect2, varscan2
- SEC31A | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs1267226557, COSV52351562; called by muse, varscan2
- SEMA5A | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV66805256; called by muse, mutect2, varscan2
- SERINC2 | c.97C>T p.R33C (on ENST00000373709 / NM_178865.5; = p.R37C on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs781806717, COSV65490033; called by muse, mutect2, varscan2
- SF3B2 | c.2429C>T p.T810M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs372951764; called by muse, mutect2, varscan2
- SH2D3C | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs781633475, COSV59129503; called by muse, mutect2, varscan2
- SHANK3 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs752413653, COSV53190980; called by muse, mutect2, varscan2
- SIPA1L2 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748564960, COSV53399741; called by muse, mutect2, varscan2
- SIRT4 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52542037; called by muse, mutect2, varscan2
- SLC12A3 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772589653, CM014394, COSV52633473, COSV99344332; called by muse, mutect2
- SLC1A6 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs540964903, COSV55669653, COSV55671594; called by muse, mutect2, varscan2
- SLC24A4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs778472920, COSV54107783; called by muse, mutect2, varscan2
- SLC25A12 | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV55537196; called by muse, mutect2, varscan2
- SLC25A15 | c.49del p.A17Lfs*9 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as COSV58556868; called by mutect2, pindel, varscan2
- SLC2A12 | c.1813T>C p.C605R | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV51602565; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC6A4 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1366793189, COSV55569682; called by muse, mutect2, varscan2
- SMC6 | c.2491A>G p.K831E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.8); PolyPhen benign (0.029); catalogued as rs746912004, COSV61178334; called by muse, mutect2, varscan2
- SMPD2 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57807056; called by muse, mutect2, varscan2
- SMYD2 | c.980_982del p.K327del | In Frame Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1347013068; called by pindel, varscan2
- SNX19 | c.2674A>G p.K892E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs769982884, COSV56288626; called by muse, mutect2, varscan2
- SNX29 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as rs149490127; called by muse, mutect2, varscan2
- SOBP | c.421+2T>C p.X141_splice | Splice Site (SNP) | VAF 34/112 reads (30%) | catalogued as COSV58002807; called by muse, mutect2, varscan2
- SORBS3 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750964341, COSV53554905; called by muse, mutect2, varscan2
- SOX1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58378395; called by muse, mutect2, varscan2
- SPAG4 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65331088; called by muse, mutect2, varscan2
- SPATA31D1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs202197407; called by muse, varscan2
- SPHK1 | c.94C>A p.Q32K (on ENST00000392496 / NM_001355139.2; = p.Q46K on NM_021972.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100039391; called by muse, mutect2, varscan2
- SPINK5 | c.306del p.G103Efs*43 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as CM160360, COSV56259428; called by mutect2, pindel, varscan2
- SPTLC3 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs370307804; called by muse, mutect2, varscan2
- SQSTM1 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV52975364; called by muse, mutect2, varscan2
- SRD5A3 | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as COSV51711330; called by muse, mutect2, varscan2
- SREBF1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.715); catalogued as COSV55419916; called by muse, mutect2, varscan2
- SREBF2 | c.2293del p.L765Wfs*13 | Frame Shift Del (DEL) | VAF 14/69 reads (20%) | catalogued as COSV63331442; called by mutect2, pindel, varscan2
- STRA6 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV60588533; called by muse, mutect2, varscan2
- STRN4 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs374013796; called by muse, mutect2, varscan2
- SUN3 | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52053942; called by muse, mutect2, varscan2
- SYNE2 | c.20069C>T p.T6690I | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs755659380, COSV59969535; called by muse, mutect2, varscan2
- SYNPO2 | c.2654A>G p.K885R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV61116904; called by muse, mutect2, varscan2
- SZT2 | c.9203G>A p.G3068D (on ENST00000634258 / NM_001365999.1; = p.G3011D on NM_015284.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65095383; called by muse, mutect2, varscan2
- TAF7 | c.250del p.T84Lfs*57 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs761173015; called by mutect2, pindel, varscan2
- TANC1 | c.2219A>G p.Q740R | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV55096730; called by muse, mutect2, varscan2
- TBC1D31 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs775746337, COSV54870910; called by muse, mutect2, varscan2
- TBL1X | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV54288401; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs758822980; called by mutect2, varscan2
- TERF2 | c.1340+2T>C p.X447_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54748994; called by muse, mutect2, varscan2
- TFIP11 | c.2078A>G p.Q693R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV53227783; called by muse, mutect2, varscan2
- TGM7 | c.2072A>G p.N691S | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV71773156; called by muse, mutect2, varscan2
- THBS2 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369355659; called by muse, mutect2, varscan2
- TKTL2 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54917577; called by muse, mutect2, varscan2
- TMEM132B | c.2551del p.Q851Sfs*39 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV54763494; called by mutect2, pindel, varscan2
- TMEM59L | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747509802, COSV53243516; called by muse, mutect2, varscan2
- TMEM68 | c.503T>C p.L168S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV58172848; called by muse, mutect2, varscan2
- TMEM94 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 47/153 reads (31%) | catalogued as COSV58599873; called by muse, mutect2, varscan2
- TNC | c.1280A>C p.E427A | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV60790257; called by muse, mutect2, varscan2
- TNKS | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60066158; called by muse, mutect2, varscan2
- TNKS | c.2900C>A p.P967H | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as COSV60064164; called by muse, mutect2, varscan2
- TNRC6A | c.3513G>T p.K1171N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV59370076; called by muse, mutect2
- TNRC6C | c.3357G>T p.Q1119H | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56952738; called by muse, mutect2, varscan2
- TNXB | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs747560876, COSV64488659; called by muse, mutect2
- TOP1MT | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as rs374238650, COSV61319768; called by muse, mutect2, varscan2
- TPGS2 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV54465429; called by muse, mutect2, varscan2
- TRIM22 | c.309del p.K103Nfs*31 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs777547311; called by mutect2, pindel, varscan2
- TRIM45 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as COSV56714886; called by muse, mutect2, varscan2
- TRIM74 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99590342; called by muse, mutect2, varscan2
- TRIO | c.3976G>A p.V1326M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60095265; called by muse, mutect2, varscan2
- TRRAP | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1554405090, COSV62838951; called by muse, mutect2, varscan2
- TSHR | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs757875222, CM107563, COSV53313995, COSV99993137; called by muse, mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | catalogued as rs1193207010; called by mutect2, varscan2
- TTC3 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61296127; called by muse, mutect2, varscan2
- TTC7A | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as rs759043996, COSV55415343; called by muse, mutect2, varscan2
- TTN | c.64949C>T p.T21650I (on ENST00000591111; = p.T14226I on NM_003319.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | PolyPhen probably damaging (0.996); catalogued as COSV60341279; called by muse, mutect2, varscan2
- TUT7 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52898847; called by muse, mutect2, varscan2
- UGT3A2 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56933405; called by muse, mutect2
- UNC13B | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774827252, COSV65931868; called by mutect2, varscan2
- UPRT | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV64920546; called by muse, mutect2, varscan2
- URI1 | c.399del p.V134* | Frame Shift Del (DEL) | VAF 4/7 reads (57%) | catalogued as rs1568443871; called by mutect2, varscan2
- USE1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs774321379, COSV55728836; called by muse, mutect2, varscan2
- USF2 | c.649dup p.R217Pfs*10 | Frame Shift Ins (INS) | VAF 35/194 reads (18%) | catalogued as rs769279094; called by mutect2, pindel, varscan2
- USHBP1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs894184808, COSV53106083; called by muse, mutect2, varscan2
- USP31 | c.3248G>A p.G1083D | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.021); catalogued as COSV54853971, COSV54857088; called by muse, mutect2, varscan2
- VPS13C | c.10576C>T p.R3526* (on ENST00000644861 / NM_020821.3; = p.R3483* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as rs779001393, COSV51120147; called by muse, mutect2, varscan2
- VPS13D | c.2882T>C p.V961A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV50682118; called by muse, mutect2
- VPS39 | c.622C>T p.P208S (on ENST00000348544 / NM_001301138.2; = p.P197S on NM_015289.5) | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1205943760, COSV58793289; called by muse, mutect2, varscan2
- VSTM4 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs777225273, COSV53679608; called by muse, mutect2, varscan2
- VWA7 | c.2369T>C p.L790P | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1562262213, COSV65174157; called by muse, mutect2, varscan2
- WASF2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs779097597, COSV71005769; called by muse, mutect2, varscan2
- WASHC2A | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50955771; called by muse, mutect2, varscan2
- WDFY3 | c.3733G>A p.V1245I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV55713549; called by muse, mutect2, varscan2
- WDR11 | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV54789595; called by muse, varscan2
- WDR13 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as rs782723344, COSV54333562; called by muse, mutect2, varscan2
- WDR53 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV60284983; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WEE2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV66880081; called by muse, mutect2, varscan2
- XKRX | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as COSV60709289; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFYVE9 | c.4193C>T p.P1398L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276115132, COSV55095178; called by muse, mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs751589999; called by mutect2, pindel, varscan2
- ZNF254 | c.1531A>T p.I511F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61644779; called by muse, mutect2, varscan2
- ZNF292 | c.7613del p.N2538Mfs*21 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as COSV100371086; called by mutect2, varscan2
- ZNF439 | c.991T>C p.C331R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58311097; called by muse, mutect2, varscan2
- ZNF462 | c.4388C>T p.P1463L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.84); catalogued as COSV52950658; called by muse, mutect2, varscan2
- ZNF462 | c.7378A>G p.S2460G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV52950671; called by muse, mutect2, varscan2
- ZNF585B | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100459452, COSV57216969; called by muse, mutect2, varscan2
- ZNF772 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1237108925, COSV58411347, COSV58411725; called by muse, mutect2, varscan2
- ZNF85 | c.131-1G>T p.X44_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100059882; called by mutect2, varscan2
- ZPBP | c.961+2T>C p.X321_splice | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as COSV50433801; called by muse, mutect2, varscan2
- ZSCAN2 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV59109245; called by muse, varscan2
- AKAP12 | c.4382del p.N1461Mfs*26 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- ANGPTL1 | c.613del p.S205Pfs*45 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.576del p.K192Nfs*3 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- ARIH2 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2
- BCORL1 | c.2678del p.G893Afs*32 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- BDP1 | c.1790del p.N597Ifs*16 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- BMP1 | c.2660del p.G887Vfs*70 | Frame Shift Del (DEL) | VAF 60/228 reads (26%) | called by mutect2, pindel, varscan2
- BOP1 | c.1364dup p.V456Rfs*51 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- CAPZB | c.604del p.T202Lfs*2 | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- CDC25C | c.1151del p.G384Afs*15 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | called by mutect2, pindel, varscan2
- CDK12 | c.2048del p.P683Qfs*70 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- CIB4 | c.216_217del p.R72Sfs*11 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- CLEC18B | c.1238+1dup p.X413_splice | Splice Site (INS) | VAF 5/38 reads (13%) | called by pindel, varscan2
- CTCF | c.2070dup p.E691Rfs*5 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- CYP4A11 | c.1268_1269del p.K423Sfs*9 | Frame Shift Del (DEL) | VAF 62/301 reads (21%) | called by mutect2, pindel, varscan2
- DDX60 | c.3580del p.T1194Pfs*8 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- DHX9 | c.3763del p.A1255Pfs*63 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- DVL1 | c.1637dup p.P547Tfs*13 (on ENST00000378888 / NM_001330311.2; = p.P522Tfs*13 on NM_004421.3) | Frame Shift Ins (INS) | VAF 8/57 reads (14%) | called by mutect2, pindel
- DYNC1H1 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- EEF2KMT | c.140_142del p.L47del | In Frame Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- EIF4EBP2 | c.120del p.T41Rfs*47 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- EIF4G2 | c.600_601del p.R200Sfs*4 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- ERBIN | c.781_783del p.S262del | In Frame Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ESRRG | c.1352del p.L451Wfs*10 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, varscan2
- EXOSC10 | c.2572del p.I858Lfs*? (on ENST00000376936 / NM_001001998.3; = p.I833Lfs*? on NM_002685.4) | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- FEZF2 | c.973del p.I325Lfs*57 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- FLNB | c.4439_4440dup p.V1481Qfs*2 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- GMFG | c.166_168del p.E56del | In Frame Del (DEL) | VAF 14/64 reads (22%) | called by pindel, varscan2
- ICE1 | c.3311del p.G1104Efs*6 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- IGLV1-36 | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- IL2RB | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); called by muse, mutect2
- JCAD | c.3088del p.A1030Qfs*35 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- KDM2B | c.2552_2555del p.Y851Sfs*82 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by pindel, varscan2
- KIAA1217 | c.543_546del p.E181Dfs*34 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by pindel, varscan2
- KIF22 | c.1774del p.I592Yfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- KLC2 | c.1708dup p.Q570Pfs*5 | Frame Shift Ins (INS) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- KLHDC8B | c.842del p.G281Afs*109 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- KMT2D | c.7417del p.Q2473Sfs*12 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- LANCL3 | c.664del p.L222* | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- LATS1 | c.646_649del p.S216Dfs*18 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- MAP2K5 | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- MBD6 | c.1189del p.Q397Nfs*90 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | called by mutect2, pindel, varscan2
- MECOM | c.2208-1_2208del p.X736_splice (on ENST00000468789 / NM_001105078.4; = p.X924_splice on NM_004991.4) | Splice Site (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- MFSD6 | c.1497del p.F499Lfs*8 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- MGA | c.4817del p.L1606* | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- MSL3 | c.1319dup p.G441Rfs*2 (on ENST00000312196 / NM_078629.4; = p.G275Rfs*2 on NM_006800.4) | Frame Shift Ins (INS) | VAF 42/221 reads (19%) | called by mutect2, pindel, varscan2
- MUC2 | c.2746T>C p.C916R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MXRA5 | c.8441del p.N2814Tfs*22 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- MYH7 | c.1941_1942del p.A649Sfs*27 | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | called by pindel, varscan2
- NCOA4 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NHLRC3 | c.462del p.G155Afs*4 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- PIGM | c.946del p.C316Vfs*10 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.1177del p.C393Afs*9 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- PLK4 | c.701del p.L234Cfs*3 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- PPP1R12B | c.2909del p.N970Mfs*88 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PRPSAP2 | c.922del p.R308Gfs*36 | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | called by mutect2, pindel, varscan2
- RABGAP1 | c.1164del p.K388Nfs*8 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- RAD51AP2 | c.946del p.T316Lfs*2 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | called by mutect2, pindel, varscan2
- RCOR2 | c.584del p.G195Afs*18 | Frame Shift Del (DEL) | VAF 60/126 reads (48%) | called by mutect2, varscan2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- RGS14 | c.710del p.G237Afs*39 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- RIF1 | c.2074del p.S692Qfs*10 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- RNF123 | c.3347del p.N1116Tfs*4 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by mutect2, pindel
- SEC24C | c.1255dup p.E419Gfs*22 | Frame Shift Ins (INS) | VAF 19/115 reads (17%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.391del p.R131Gfs*15 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- SIN3B | c.2328del p.F776Lfs*21 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, varscan2
- SPEG | c.3380del p.G1127Afs*27 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- SPPL2B | c.383del p.G128Vfs*32 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- STAP1 | c.480del p.E161Rfs*12 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | called by mutect2, pindel, varscan2
- SUGP2 | c.763del p.I255Yfs*4 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | called by mutect2, varscan2
- TAF1 | c.675del p.F225Lfs*25 (on ENST00000373790 / NM_138923.4; = p.F246Lfs*25 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- TG | c.8052del p.W2685Gfs*26 | Frame Shift Del (DEL) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- THYN1 | c.581del p.N194Ifs*15 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- TLE4 | c.473dup p.A159Cfs*7 | Frame Shift Ins (INS) | VAF 33/147 reads (22%) | called by mutect2, pindel, varscan2
- TMEM14A | c.102del p.F34Lfs*20 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- TNS2 | c.3515_3517del p.G1172del (on ENST00000314250 / NM_170754.4; = p.G1182del on NM_015319.2) | In Frame Del (DEL) | VAF 37/176 reads (21%) | called by mutect2, pindel, varscan2
- TPP2 | c.353_354del p.Y118* | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- TRAF3 | c.1624_1625del p.V542Sfs*8 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- TRGV5 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBN2 | c.2135del p.K712Rfs*45 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- UGT1A10 | c.364del p.S122Rfs*12 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- UHRF1BP1L | c.2543dup p.T849Nfs*6 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- VCL | c.872del p.P291Qfs*13 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- VHLL | c.390dup p.A131Cfs*59 | Frame Shift Ins (INS) | VAF 13/112 reads (12%) | called by mutect2, pindel, varscan2
- VPS13B | c.173del p.L58* | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- ZNF692 | c.327dup p.L110Afs*54 | Frame Shift Ins (INS) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- ZRANB1 | c.753del p.K251Nfs*2 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- AASDH | c.963G>A p.A321= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs768281923, COSV52710583; called by muse, varscan2
- ABCA12 | c.561C>T p.S187= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55975040; called by muse, mutect2, varscan2
- ADAM17 | c.2424C>A p.S808= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV60401851; called by muse, mutect2, varscan2
- ADAM23 | c.2136G>A p.T712= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs540645451, COSV52208293; called by muse, mutect2, varscan2
- ADAMTS7 | c.825T>C p.A275= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV66309385; called by muse, mutect2, varscan2
- AGTPBP1 | c.2628T>C p.D876= (on ENST00000357081 / NM_001330701.2; = p.D836= on NM_015239.2) | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV61277306; called by mutect2, varscan2
- AP002512.3 | c.1002C>T p.A334= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs1454477369, COSV54408723; called by mutect2, varscan2
- AQP11 | c.325C>T p.L109= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV57993178; called by muse, mutect2
- ARHGEF16 | c.1959G>A p.A653= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as rs1364080724, COSV65683188; called by muse, mutect2, varscan2
- ARL4C | c.147C>T p.T49= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV60214618; called by muse, mutect2, varscan2
- ASB9 | c.39C>T p.P13= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs761036835, COSV66852309; called by muse, mutect2, varscan2
- ATP5F1A | c.1392C>T p.G464= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs143320751; called by muse, mutect2, varscan2
- AZI2 | c.54T>C p.H18= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV55425414; called by muse, mutect2
- B4GALNT3 | c.2163C>T p.R721= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs150429681; called by muse, mutect2, varscan2
- BAZ1A | c.744G>A p.T248= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1309627549, COSV62411892; called by muse, mutect2, varscan2
- BCL11B | c.2019C>T p.P673= (on ENST00000357195 / NM_001282237.2; = p.P602= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs777226398, COSV61739259; called by muse, mutect2
- BEX1 | c.363T>C p.F121= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as COSV65580679; called by muse, mutect2, varscan2
- BOC | c.129G>A p.A43= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs752378926, COSV56349313; called by muse, mutect2, varscan2
- BPI | c.1317T>C p.I439= (on ENST00000262865; = p.I435= on NM_001725.3) | Silent (SNP) | VAF 71/281 reads (25%) | catalogued as COSV53408389; called by muse, mutect2, varscan2
- BSN | c.3318G>A p.T1106= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs139466364, COSV56527145; called by muse, mutect2, varscan2
- CALHM2 | c.210C>T p.I70= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs1416129503, COSV53297825; called by muse, mutect2
- CALU | c.246C>T p.G82= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1437131408, COSV99975715; called by muse, mutect2, varscan2
- CDH1 | c.699C>T p.H233= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs115494727, COSV55727536, COSV55740683; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CEACAM5 | c.1695C>T p.D565= | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as rs782644830, COSV55751523; called by muse, mutect2, varscan2
- CEACAM7 | c.615C>T p.S205= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as rs200263190, COSV50074735; called by muse, mutect2, varscan2
- CHD2 | c.1302A>G p.G434= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs765523530, COSV59122416; called by muse, mutect2, varscan2
- CHD5 | c.1695C>T p.S565= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs992073301, COSV52424612; called by muse, mutect2, varscan2
- CHRM5 | c.294C>T p.L98= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs368054329, COSV101271844; called by muse, mutect2, varscan2
- CIAO3 | c.645G>A p.P215= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs757733391, COSV52403665; called by muse, mutect2, varscan2
- CIC | c.369G>A p.P123= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs534081429, COSV50663400; called by muse, varscan2
- CLEC10A | c.882C>T p.D294= (on ENST00000254868 / NM_182906.4; = p.D270= on NM_006344.4) | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs139844327; called by muse, mutect2, varscan2
- CLIC3 | c.168C>T p.F56= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV65406869; called by muse, mutect2, varscan2
- CMIP | c.1308C>T p.P436= (on ENST00000537098 / NM_198390.2; = p.P342= on NM_030629.3) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs747368835, COSV67700291; called by muse, mutect2, varscan2
- COL6A2 | c.2343G>A p.Q781= | Silent (SNP) | VAF 71/416 reads (17%) | catalogued as rs767950061, COSV56015790; called by muse, mutect2, varscan2
- COL6A3 | c.4155C>T p.P1385= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs761804539, COSV55082238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRHR1 | c.600G>A p.V200= (on ENST00000398285 / NM_001145146.2; = p.V171= on NM_004382.5) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV53285884; called by muse, mutect2, varscan2
- CRIP2 | c.549C>T p.F183= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as rs781783153, COSV61275017; called by muse, mutect2, varscan2
- CSMD1 | c.6366C>T p.G2122= (on ENST00000520002; = p.G2121= on NM_033225.6) | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59288798; called by muse, mutect2, varscan2
- CTNNA2 | c.981G>A p.R327= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs745441744, COSV63549626; called by muse, mutect2, varscan2
- CTSZ | c.357C>T p.S119= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs770416644, COSV53884799; called by muse, varscan2
- CYP4F22 | c.681T>C p.S227= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV54109484; called by muse, mutect2, varscan2
- DENND3 | c.3201T>C p.I1067= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52806761; called by muse, mutect2, varscan2
- DMPK | c.1026C>T p.L342= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs769610342, COSV52182237; called by muse, mutect2, varscan2
- DMRT2 | c.981C>T p.S327= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs371344054; called by muse, mutect2, varscan2
- DNAH3 | c.7746G>A p.S2582= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs763356860, COSV54521378; called by muse, mutect2, varscan2
- DNAH8 | c.8775T>C p.P2925= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59479621; called by muse, mutect2, varscan2
- DNAI2 | c.1152C>T p.G384= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs762652711, COSV56759184; called by muse, mutect2, varscan2
- DNAJB14 | c.978T>C p.T326= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs1439005416, COSV62036224; called by muse, mutect2, varscan2
- DNAJC14 | c.1602T>C p.T534= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV54479335; called by muse, mutect2, varscan2
- DYNC1I2 | c.321C>T p.G107= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs753569691, COSV55525241, COSV55527458; called by muse, mutect2, varscan2
- E2F5 | c.675T>C p.H225= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1352645679, COSV56276331; called by muse, mutect2, varscan2
- EFCAB6 | c.1911G>A p.P637= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs150612043; called by muse, mutect2, varscan2
- EFNA5 | c.588C>T p.A196= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs773576170, COSV60957652; called by mutect2, varscan2
- EIF3K | c.315C>T p.L105= | Silent (SNP) | VAF 57/225 reads (25%) | catalogued as rs746185236, COSV50264570; called by muse, mutect2, varscan2
- EMID1 | c.372G>A p.R124= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV61830817; called by muse, mutect2, varscan2
- ENTPD4 | c.1515G>A p.S505= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs1184433422, COSV62269512; called by muse, varscan2
- EPHX3 | c.165C>T p.C55= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV54583976; called by muse, mutect2, varscan2
- ESPNL | c.2934C>T p.N978= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs182590742, COSV58038139; called by muse, mutect2, varscan2
- EVPL | c.504C>T p.Y168= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs751241976, COSV56913448, COSV56915667; called by muse, mutect2, varscan2
- EYS | c.501G>C p.V167= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV60982923; called by muse, mutect2, varscan2
- F5 | c.2454A>G p.S818= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV63128274; called by muse, varscan2
- FAM102A | c.999C>T p.I333= (on ENST00000373095 / NM_001035254.3; = p.I191= on NM_203305.2) | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs753057132, COSV55947595; called by muse, mutect2, varscan2
- FASTKD5 | c.87A>G p.S29= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs766403475, COSV53909571; called by muse, mutect2, varscan2
- FBF1 | c.2898C>T p.T966= (on ENST00000586717; = p.T981= on NM_001319193.1) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs377502076, COSV59866997; called by muse, mutect2, varscan2
- FBN3 | c.987G>A p.P329= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs778547878, COSV54472343; called by muse, mutect2, varscan2
- FBXW10 | c.1986C>T p.S662= | Silent (SNP) | VAF 81/308 reads (26%) | catalogued as COSV57322208; called by muse, mutect2, varscan2
- FBXW4 | c.756G>A p.V252= | Silent (SNP) | VAF 58/198 reads (29%) | catalogued as COSV58709715; called by muse, mutect2, varscan2
- FKBP11 | c.207A>G p.V69= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV56740249; called by muse, mutect2, varscan2
- FLT1 | c.3897C>T p.H1299= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs1197323919, COSV56742651; called by muse, mutect2, varscan2
- FOXE1 | c.1056C>T p.G352= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV64301020; called by muse, mutect2, varscan2
- FOXK1 | c.777C>T p.R259= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs767558881, COSV61068674; called by muse, mutect2, varscan2
- FOXO4 | c.1230G>A p.T410= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs760792736, COSV58575626, COSV58576446; called by muse, mutect2, varscan2
- FRMPD4 | c.2244G>A p.A748= | Silent (SNP) | VAF 40/151 reads (26%) | catalogued as rs771141078, COSV66223255; called by muse, mutect2, varscan2
- GART | c.252G>A p.G84= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs773415473, COSV63114677; called by muse, mutect2, varscan2
- GAS2 | c.219T>C p.T73= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV53412622; called by muse, mutect2, varscan2
- GAS6 | c.990C>T p.P330= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs747914644, COSV59855718; called by muse, mutect2, varscan2
- GDF10 | c.1056G>A p.S352= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- GFM2 | c.276C>T p.Y92= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57193356; called by mutect2, varscan2
- GGTLC2 | c.486G>A p.T162= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs541898269, COSV67854485; called by muse, mutect2, varscan2
- GREB1 | c.2854C>T p.L952= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV52196118; called by muse, mutect2, varscan2
- GRIA4 | c.1164T>C p.G388= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1308688417, COSV56919061; called by muse, mutect2, varscan2
- GRIN3B | c.594C>T p.P198= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1212373786, COSV52262285; called by muse, mutect2
- GUCY2C | c.1092C>T p.D364= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs544933759, COSV53788142; called by muse, mutect2, varscan2
- HMCN1 | c.5973C>T p.C1991= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs751057536, COSV54940484; called by muse, mutect2, varscan2
- HMCN1 | c.15114A>G p.T5038= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99630500; called by muse, mutect2, varscan2
- HPS4 | c.1455G>A p.T485= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as rs756215705, COSV100404277, COSV61105266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSD17B14 | c.759C>T p.Y253= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs371019958, COSV54415263; called by muse, mutect2, varscan2
- IRF3 | c.711G>A p.T237= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs376377408, COSV55864581; called by muse, mutect2, varscan2
- ITPR3 | c.225G>A p.K75= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV65414772; called by muse, mutect2, varscan2
- KCNA5 | c.918G>A p.P306= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV52904410; called by muse, mutect2, varscan2
- KCNB1 | c.840C>T p.T280= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs748523037, COSV65570796; called by muse, mutect2, varscan2
- KCNJ4 | c.795C>T p.I265= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs773072604, COSV57857004; called by muse, mutect2, varscan2
- KCNK3 | c.525C>T p.A175= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV57193525, COSV57194348; called by muse, mutect2, varscan2
- KCNMA1 | c.3054T>C p.D1018= (on ENST00000286628 / NM_001161352.2; = p.D960= on NM_002247.4) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1370293783, COSV99697985; called by muse, mutect2, varscan2
- KEAP1 | c.444C>T p.G148= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs11545828; called by muse, mutect2, varscan2
- KIF6 | c.2109C>T p.L703= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs763515741, COSV54666634; called by muse, mutect2, varscan2
- KNL1 | c.2970C>T p.Y990= (on ENST00000346991 / NM_170589.5; = p.Y964= on NM_144508.5) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV61160286; called by muse, mutect2, varscan2
- KRT23 | c.240C>T p.N80= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as COSV52927454; called by muse, mutect2, varscan2
139 further variants in this file (0 protein-altering or splice-affecting, 126 silent, 13 other) are not listed here.
